Somatic mutation profile of tumor specimen TCGA-12-0657-01A (aliquot TCGA-12-0657-01A-01W-0348-08) from TCGA case TCGA-12-0657, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.6 years (25,413 days).
Specimen TCGA-12-0657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa573ece-2492-496a-9364-665cb2090774.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0657-10A (Blood Derived Normal), aliquot TCGA-12-0657-10A-01W-0348-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b730dd94-2a2d-4fef-9bf7-d3ee4b5c2003

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Frame Shift Ins 4, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 919/2018 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- BRAP | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 16/465 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV100553925; called by muse, mutect2
- C2CD3 | c.4168G>A p.E1390K | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100486154; called by muse, mutect2
- CANX | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 154/355 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV99910149; called by muse, mutect2, varscan2
- CFH | c.2048T>A p.V683E | Missense Mutation (SNP) | VAF 326/760 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV100808609; called by muse, varscan2
- EBF1 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.001); catalogued as COSV100565003; called by muse, mutect2, varscan2
- EGFR | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 566/4351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765137528; called by muse, varscan2
- EGFR | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 143/1180 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs772046081, COSV51772147; called by muse, mutect2, varscan2
- FLG | c.10304G>A p.R3435H | Missense Mutation (SNP) | VAF 353/885 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs576274425, COSV64241308; called by muse, mutect2, varscan2
- GUCY2D | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as rs774420737, COSV54696562; called by muse, varscan2
- GUCY2D | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV99643666; called by muse, varscan2
- IL18R1 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV99294831; called by muse, mutect2
- ITIH4 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs754898084, COSV99818791; called by muse, varscan2
- KPRP | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs752074154, COSV64220853; called by muse, mutect2, varscan2
- LIMK1 | c.1730dup p.S578Efs*67 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs781852315; called by pindel, varscan2
- LRP10 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.13); catalogued as rs777666106, COSV100612243; called by mutect2, varscan2
- MYO5A | c.4895A>T p.H1632L | Missense Mutation (SNP) | VAF 163/305 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV100697207; called by muse, mutect2, varscan2
- NLRP1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs145709003; called by muse, mutect2, varscan2
- OR14I1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs758276680, COSV100700410; called by muse, mutect2, varscan2
- OR1M1 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 426/891 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV101447530; called by muse, mutect2, varscan2
- OR1M1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV101447531; called by muse, mutect2, varscan2
- OR2M4 | c.244A>C p.I82L | Missense Mutation (SNP) | VAF 384/883 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100140921; called by muse, mutect2, varscan2
- OR5P2 | c.171C>A p.F57L | Missense Mutation (SNP) | VAF 26/383 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs778184529, COSV100271158; called by muse, mutect2
- PALD1 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99697839; called by muse, mutect2, varscan2
- PDCL3 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV99959410; called by muse, mutect2
- PIEZO2 | c.7771G>A p.V2591M | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs558652174, COSV99554316; called by muse, mutect2, varscan2
- PIGU | c.1128G>A p.W376* | Nonsense Mutation (SNP) | VAF 133/336 reads (40%) | catalogued as COSV99465806; called by muse, mutect2, varscan2
- PIWIL4 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs753261810, COSV54408609; called by muse, mutect2, varscan2
- PRSS16 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100041479; called by muse, mutect2, varscan2
- PYM1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV56811536; called by muse, mutect2, varscan2
- RPS3A | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 113/274 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99923585; called by muse, mutect2, varscan2
- RYR3 | c.3739G>A p.V1247M | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs777516148, COSV101211839; called by muse, mutect2, varscan2
- SCN11A | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs774609057, COSV56571080; called by muse, mutect2, varscan2
- SIRPB1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 218/249 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs139862493; called by muse, mutect2, varscan2
- SLC22A6 | c.1268G>C p.R423P | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753182993, COSV100842775; called by muse, mutect2, varscan2
- SLC26A3 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 15/416 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100384772; called by muse, mutect2
- SLCO2B1 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754251441, COSV99214159; called by muse, mutect2, varscan2
- SND1 | c.2191dup p.R731Pfs*35 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | catalogued as rs762301654; called by mutect2, pindel
- SPEF2 | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs751703258, COSV100606017; called by muse, mutect2
- STK31 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 477/1621 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757104552, COSV63453939, COSV63459549; called by muse, mutect2, varscan2
- WDR11 | c.2216G>T p.G739V | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV99676160; called by muse, mutect2
- WDR45B | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66409034; called by muse, mutect2, varscan2
- ZCRB1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99861140; called by muse, mutect2, varscan2
- BMF | c.363dup p.E122Rfs*63 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by pindel, varscan2
- CHD8 | c.2975_2976del p.H992Lfs*34 (on ENST00000646647 / NM_001170629.2; = p.H713Lfs*34 on NM_020920.4) | Frame Shift Del (DEL) | VAF 130/394 reads (33%) | called by mutect2, pindel, varscan2
- GOLIM4 | c.444A>C p.R148S | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PCDHGC3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PSMD7 | c.140dup p.L48Tfs*2 | Frame Shift Ins (INS) | VAF 80/199 reads (40%) | called by mutect2, pindel, varscan2
- STARD3 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ACTR3 | c.483G>A p.R161= | Silent (SNP) | VAF 692/2279 reads (30%) | catalogued as COSV99603306; called by muse, mutect2, varscan2
- ADAMTS16 | c.2241T>C p.I747= | Silent (SNP) | VAF 376/492 reads (76%) | catalogued as COSV99939690; called by muse, mutect2, varscan2
- CD163L1 | c.3894C>T p.D1298= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs748315306, COSV58026152; called by muse, mutect2, varscan2
- DENND2D | c.984C>T p.V328= | Silent (SNP) | VAF 53/447 reads (12%) | catalogued as COSV100718455; called by muse, mutect2, varscan2
- GPX3 | c.189C>T p.Y63= | Silent (SNP) | VAF 66/154 reads (43%) | catalogued as rs766813820, COSV100161051; called by muse, mutect2, varscan2
- IL6R | c.144G>A p.P48= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs1365223291, COSV59817362; called by muse, mutect2, varscan2
- KCNA6 | c.441C>T p.D147= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV54975011; called by muse, mutect2, varscan2
- LAMA1 | c.3549T>C p.S1183= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs1166314560, COSV101054666; called by muse, mutect2, varscan2
- LPIN1 | c.426C>T p.P142= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99876848; called by muse, mutect2
- NLRP9 | c.537C>T p.F179= | Silent (SNP) | VAF 82/171 reads (48%) | catalogued as COSV100242473; called by muse, mutect2, varscan2
- S100A7 | c.42C>T p.I14= | Silent (SNP) | VAF 94/1098 reads (9%) | catalogued as COSV64193408; called by muse, mutect2
- SLC25A6 | c.630C>T p.I210= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs780007250, COSV58431896; called by muse, mutect2, varscan2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 88/195 reads (45%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- TAB2 | c.1959A>G p.K653= | Silent (SNP) | VAF 105/283 reads (37%) | catalogued as rs111920140, COSV99644431; called by muse, mutect2, varscan2
- TECR | c.303C>T p.I101= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV99294993; called by muse, mutect2, varscan2
- TSGA13 | c.285G>A p.T95= | Silent (SNP) | VAF 21/405 reads (5%) | catalogued as rs201751276, COSV100746762; called by muse, mutect2
- VANGL1 | c.1299C>T p.N433= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs145137292; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZNF98 | c.364T>C p.L122= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100757248; called by muse, mutect2
- AP001267.5 | c.-835C>T | 5'UTR (SNP) | VAF 10/43 reads (23%) | catalogued as rs1420290078, COSV99347783; called by muse, mutect2
